Gene-level copy-number profile of specimen HCM-BROD-0472-C34-85M from HCMI case HCM-BROD-0472-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.9 years (24,082 days).
Specimen HCM-BROD-0472-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94ea4c20-d6f2-4c5c-81f8-0eccf0a895b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0472-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/a9e4529a-ca47-4b05-aa11-328463ff8eb8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,323; copy number 2: 19,528; copy number 3: 21,879; copy number 4: 9,537; copy number 5: 5,619; copy number 6: 985; copy number 7: 28; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes, copy number 7: AC119751.4, SNX18P25.
- chr6:20,212,087–21,523,783, 14 genes, copy number 7 (within-gene range 3–7): AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1.
- chr9:60,914,407–60,964,196, 5 genes, copy number 7: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:61,659,733–61,662,690, 1 gene, copy number 9: AL935212.1.
- chr18:23,598,926–23,956,222, 4 genes, copy number 7: ANKRD29, RPS10P27, LAMA3, RPL23AP77.
- chr18:24,534,551–24,708,542, 3 genes, copy number 7: LINC01915, RAC1P1, PPIAP57.

Autosomal genes at a single copy (total copy number 1): 1,323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
